Somatic mutation profile of tumor specimen TARGET-20-PARCVS-04A (aliquot TARGET-20-PARCVS-04A-01D) from TARGET case TARGET-20-PARCVS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,600 days).
Specimen TARGET-20-PARCVS-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e50b0afb-6522-4220-9554-410a71957416.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARCVS-14A (Bone Marrow Normal), aliquot TARGET-20-PARCVS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc3b3d19-5e44-44a6-8e5d-26a44c246825

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.3805G>T p.G1269* | Nonsense Mutation (SNP) | VAF 68/181 reads (38%) | catalogued as COSV54332385; called by muse, mutect2, varscan2
- GAREM1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52509279; called by muse, mutect2, varscan2
- PRKDC | c.12269G>A p.R4090H | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769900148, COSV58051561; called by muse, mutect2, varscan2
- SUPT5H | c.3242T>A p.L1081Q | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58679447; called by muse, mutect2, varscan2
- CREBBP | c.1760dup p.V588Cfs*20 | Frame Shift Ins (INS) | VAF 38/124 reads (31%) | called by mutect2, pindel, varscan2
